Gene-level copy-number profile of tumor specimen TCGA-BL-A5ZZ-01A from TCGA case TCGA-BL-A5ZZ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 80.1 years (29,247 days).
Specimen TCGA-BL-A5ZZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.624e9a2a-d514-4cba-8fb9-adabdd7e268c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BL-A5ZZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/634fd897-d849-481b-b50e-4fe4699bd2e2

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 1,620; copy number 3: 142; copy number 4: 37,745; copy number 5: 433; copy number 6: 19,195; copy number 7: 187; copy number 9: 474; copy number 10: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BL-A5ZZ-01A-31D-A30D-01): tumor purity 0.38, ploidy 2.31, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 498 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:84,668,551–110,172,512, 474 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr19:22,391,019–22,716,991, 24 genes, copy number 10 (within-gene range 5–10): ZNF98, AC011516.1, BNIP3P32, AC025811.1, BNIP3P33, ZNF209P, AC004004.1, AC011467.6, AC011467.1, LINC01233, RNU6-1179P, AC011467.5, GOLGA2P9, RN7SL860P, AC011467.3, AC011467.4, RAD54L2P1, LINC01785, AC011467.2, ZNF492, AC024563.1, ZNF849P, RPL34P33, AC024563.2.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
